Somatic mutation profile of tumor specimen TCGA-FR-A3YN-06A (aliquot TCGA-FR-A3YN-06A-11D-A23B-08) from TCGA case TCGA-FR-A3YN, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 50.8 years (18,546 days).
Specimen TCGA-FR-A3YN-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 984a7791-4513-4c84-baf4-f3cbcf6651c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FR-A3YN-10A (Blood Derived Normal), aliquot TCGA-FR-A3YN-10A-01D-A23B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1165cfbd-ac66-4619-8d5e-acd3fc89fb8a

The open-access MAF lists 692 somatic variants for this specimen: 437 protein-altering or splice-affecting, 239 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 390, Silent 239, Nonsense Mutation 29, 3'UTR 7, Splice Region 6, Splice Site 4, Intron 4, RNA 4, Frame Shift Del 3, Translation Start Site 2, In Frame Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNOT9 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 115/353 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs267599211, COSV55298957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 33/72 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV54070357; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 224/351 reads (64%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.4573C>T p.R1525* (on ENST00000303395 / NM_001202435.3; = p.R1514* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 34/105 reads (32%) | catalogued as rs794726752, CM065456, COSV57659034, COSV57669725; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.3832A>G p.K1278E | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.146); catalogued as COSV55950957; called by muse, mutect2, varscan2
- ACOX1 | c.566T>C p.V189A | Missense Mutation (SNP) | VAF 106/313 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV53133272; called by muse, mutect2, varscan2
- ACSM2B | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 76/137 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV61657824; called by muse, mutect2, varscan2
- ACTL9 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.324); catalogued as rs782524837, COSV61005237; called by muse, mutect2, varscan2
- ADAM19 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV57429875; called by muse, mutect2, varscan2
- ADAMTS18 | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as rs149929752, COSV51405141; called by muse, mutect2, varscan2
- ADAMTS20 | c.3934C>T p.P1312S | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs562619092, COSV67131331; called by muse, mutect2, varscan2
- ADAMTSL2 | c.284A>G p.K95R | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV63204098; called by muse, mutect2, varscan2
- ADGRB3 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.54); PolyPhen benign (0.026); catalogued as COSV65394758; called by muse, mutect2, varscan2
- ADGRG3 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0.105); catalogued as COSV59651092; called by muse, mutect2, varscan2
- ADGRL4 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as COSV66061598; called by muse, mutect2, varscan2
- ADH1C | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV72463461; called by muse, mutect2, varscan2
- ANGPT1 | c.1343G>A p.W448* | Nonsense Mutation (SNP) | VAF 49/97 reads (51%) | catalogued as COSV52439724; called by muse, mutect2, varscan2
- ANK3 | c.13105C>T p.R4369W (on ENST00000280772 / NM_001320874.2; = p.R993W on NM_001149.3) | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs556782173, COSV55057446; called by muse, mutect2, varscan2
- ANK3 | c.6604G>A p.E2202K | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.115); catalogued as COSV55057459; called by muse, mutect2, varscan2
- ANKRD34B | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as COSV100103565, COSV58613886; called by muse, mutect2, varscan2
- ANKRD50 | c.3226C>T p.Q1076* | Nonsense Mutation (SNP) | VAF 91/149 reads (61%) | catalogued as COSV72385538; called by muse, mutect2, varscan2
- APC | c.4856C>T p.P1619L | Missense Mutation (SNP) | VAF 102/186 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV57343658; called by muse, mutect2, varscan2
- ARF5 | c.259-1G>A p.X87_splice | Splice Site (SNP) | VAF 63/173 reads (36%) | catalogued as COSV50000971; called by muse, mutect2, varscan2
- ARHGAP33 | c.3079T>G p.S1027A | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.193); catalogued as COSV50123287; called by muse, mutect2, varscan2
- ARMC3 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.745); catalogued as COSV53061151; called by muse, mutect2, varscan2
- ASXL3 | c.4603C>T p.H1535Y | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); catalogued as COSV52465711; called by muse, mutect2, varscan2
- ASZ1 | c.364C>T p.H122Y | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs757218513, COSV52912793; called by muse, mutect2, varscan2
- ATN1 | c.1931C>T p.P644L | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.209); catalogued as rs781978577, COSV63111017; called by muse, mutect2, varscan2
- ATP13A2 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV58700445; called by muse, mutect2, varscan2
- ATP1A4 | c.2878T>A p.L960I | Missense Mutation (SNP) | VAF 205/321 reads (64%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as rs367919964; called by muse, mutect2, varscan2
- BAHCC1 | c.1411C>T p.L471F | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.8); catalogued as COSV57026543; called by muse, mutect2, varscan2
- BANK1 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59842557; called by muse, mutect2, varscan2
- BEGAIN | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.306); catalogued as COSV100766960; called by muse, mutect2
- BMPER | c.1537G>A p.G513R | Missense Mutation (SNP) | VAF 78/137 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51818222; called by muse, mutect2, varscan2
- BNIP5 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV71325530; called by muse, mutect2, varscan2
- BNIPL | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54846910; called by muse, mutect2, varscan2
- BTNL3 | c.812G>A p.W271* | Nonsense Mutation (SNP) | VAF 29/124 reads (23%) | catalogued as COSV100732208; called by muse, mutect2, varscan2
- BTNL8 | c.677C>T p.T226I | Missense Mutation (SNP) | VAF 64/319 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.076); catalogued as rs757320411, COSV99180479; called by muse, mutect2, varscan2
- C11orf40 | n.142G>A | Splice Region (SNP) | VAF 26/38 reads (68%) | catalogued as COSV56890552; called by muse, mutect2, varscan2
- C12orf50 | c.1175T>C p.I392T | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.794); catalogued as COSV53895209; called by muse, mutect2, varscan2
- C6 | c.2069G>A p.G690E | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.744); catalogued as COSV54709977; called by muse, mutect2, varscan2
- C6 | c.1354G>A p.G452R | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV54709987; called by muse, mutect2, varscan2
- C7 | c.1928A>G p.H643R | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.139); catalogued as COSV57474230; called by muse, mutect2, varscan2
- C8A | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 154/228 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV63483992; called by muse, mutect2, varscan2
- C9orf131 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 70/94 reads (74%) | SIFT tolerated (0.72); PolyPhen benign (0.234); catalogued as rs1475559020, COSV100397964, COSV56610626; called by muse, mutect2, varscan2
- CACNG2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV55634841; called by muse, mutect2, varscan2
- CALCOCO2 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 67/247 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51951905, COSV51952983; called by muse, mutect2, varscan2
- CATSPERB | c.1242G>A p.M414I | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV56426334; called by muse, mutect2, varscan2
- CBLB | c.2713C>T p.P905S | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.996); catalogued as COSV51426495; called by muse, mutect2, varscan2
- CCDC88C | c.2003G>A p.S668N | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66237842; called by muse, mutect2, varscan2
- CCNJ | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as rs773082239, COSV56442964; called by muse, mutect2, varscan2
- CCSER1 | c.1674G>A p.M558I | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV61429883; called by muse, mutect2, varscan2
- CD163L1 | c.4046C>T p.S1349L | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs771878446, COSV58015947; called by muse, mutect2
- CD36 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59212884; called by muse, mutect2, varscan2
- CDH10 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.062); catalogued as COSV52576110; called by muse, mutect2, varscan2
- CDH4 | c.2632G>A p.G878S | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.997); catalogued as COSV64654234; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2771C>T p.S924F | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.548); catalogued as COSV62574230; called by muse, mutect2, varscan2
- CDSN | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs764535227, COSV52538076; called by muse, mutect2, varscan2
- CEMIP | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as rs540926515, COSV54991164; called by muse, mutect2, varscan2
- CERKL | c.1540G>A p.E514K (on ENST00000339098 / NM_001030311.2; = p.E488K on NM_201548.5) | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV59202412; called by muse, mutect2, varscan2
- CFAP100 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.667); catalogued as COSV61502290, COSV61503096; called by muse, mutect2, varscan2
- CFAP74 | c.80T>A p.L27* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV54567591; called by muse, mutect2, varscan2
- CHGA | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 65/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1395422852, COSV53663206; called by muse, mutect2, varscan2
- CHL1 | c.2573G>A p.G858E (on ENST00000397491 / NM_001253387.1; = p.G874E on NM_006614.4) | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.97); PolyPhen benign (0.011); catalogued as COSV56593201, COSV56596862; called by muse, mutect2, varscan2
- CHRM2 | c.231G>A p.M77I | Missense Mutation (SNP) | VAF 202/327 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV57772049; called by muse, mutect2, varscan2
- CHST15 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as COSV60562113; called by muse, mutect2, varscan2
- CLVS2 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.605); catalogued as COSV51562421; called by muse, mutect2, varscan2
- CNKSR2 | c.2510G>A p.G837E | Missense Mutation (SNP) | VAF 59/72 reads (82%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as COSV54255998; called by muse, mutect2, varscan2
- CNTN5 | c.2723G>A p.G908E | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54282866; called by muse, mutect2, varscan2
- COL11A1 | c.1845+1G>A p.X615_splice | Splice Site (SNP) | VAF 126/204 reads (62%) | catalogued as COSV62183395; called by muse, mutect2, varscan2
- COL2A1 | c.3608G>A p.G1203E | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61530436; called by muse, mutect2, varscan2
- COL6A3 | c.5419G>A p.E1807K | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs781624176, COSV55088791; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- COL9A3 | c.1948C>T p.P650S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV53896047; called by muse, mutect2, varscan2
- CP | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 67/132 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52830548; called by muse, mutect2, varscan2
- CPD | c.4033G>T p.E1345* | Nonsense Mutation (SNP) | VAF 201/345 reads (58%) | catalogued as COSV56712773; called by muse, mutect2, varscan2
- CPO | c.265A>C p.K89Q | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.611); catalogued as COSV55939782; called by muse, mutect2
- CSMD2 | c.9605G>A p.G3202E | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (1); PolyPhen possibly damaging (0.61); catalogued as COSV53911333; called by muse, mutect2, varscan2
- CSMD2 | c.8513C>T p.P2838L | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs1298140390, COSV53911346; called by muse, mutect2, varscan2
- CSMD2 | c.7393G>A p.A2465T | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV53911363, COSV99591898; called by muse, mutect2, varscan2
- CSMD2 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355609119, COSV53911378; called by muse, mutect2, varscan2
- CSN3 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.875); catalogued as rs746268983, COSV100515408, COSV59243925; called by muse, mutect2, varscan2
- CTNNA2 | c.2800C>T p.Q934* (on ENST00000402739 / NM_001282597.3; = p.Q886* on NM_004389.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 77/237 reads (32%) | catalogued as COSV58152011, COSV58165937; called by muse, mutect2, varscan2
- CTNND2 | c.2315C>T p.S772L | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs867204139, COSV58867189; called by muse, varscan2
- CWH43 | c.944C>T p.T315I | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99893443; called by muse, mutect2, varscan2
- CYP2C19 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.343); catalogued as COSV64907608; called by muse, mutect2, varscan2
- CYP4F22 | c.385G>C p.D129H | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54108363; called by muse, mutect2, varscan2
- DCAF11 | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58108057, COSV58109130; called by muse, mutect2, varscan2
- DCAF12 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV63512473; called by muse, mutect2, varscan2
- DCAF12L1 | c.66C>G p.S22R | Missense Mutation (SNP) | VAF 35/39 reads (90%) | SIFT tolerated (0.16); PolyPhen benign (0.296); catalogued as COSV64421775; called by muse, mutect2, varscan2
- DCAF4L2 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.816); catalogued as COSV60476153, COSV60479913; called by muse, mutect2, varscan2
- DCAF8L1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 44/50 reads (88%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.831); catalogued as rs769053531, COSV71595254, COSV71595276; called by muse, mutect2, varscan2
- DCDC2 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.275); catalogued as COSV65828718; called by muse, varscan2
- DCN | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV50006179, COSV50008176; called by muse, mutect2, varscan2
- DCST1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 58/90 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV55059295; called by muse, mutect2, varscan2
- DCTN1 | c.118C>T p.H40Y | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV62620469; called by muse, mutect2, varscan2
- DDX5 | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 112/367 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56749041; called by muse, mutect2, varscan2
- DEFA4 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.942); catalogued as rs868785648, COSV52404722; called by muse, mutect2, varscan2
- DEFB121 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.887); catalogued as COSV66236286; called by muse, mutect2, varscan2
- DENND5B | c.3782C>T p.T1261I | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV60902483, COSV60909442; called by muse, mutect2, varscan2
- DLGAP2 | c.1729C>T p.Q577* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as COSV70098021, COSV70101977; called by muse, mutect2, varscan2
- DNAH8 | c.12226G>A p.E4076K | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773290369, COSV59433599; called by muse, mutect2, varscan2
- DNAH9 | c.7913G>A p.G2638E | Missense Mutation (SNP) | VAF 125/172 reads (73%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV52349017; called by muse, mutect2, varscan2
- DSC3 | c.872C>A p.S291* | Nonsense Mutation (SNP) | VAF 43/92 reads (47%) | catalogued as COSV64572931; called by muse, mutect2, varscan2
- DUSP15 | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1301409817, COSV54066182; called by muse, mutect2, varscan2
- DUSP22 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.282); catalogued as COSV60526272, COSV60527844; called by muse, mutect2, varscan2
- ECT2 | c.2501C>T p.S834L (on ENST00000392692 / NM_001349098.2; = p.S803L on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV51688733, COSV99222002; called by muse, mutect2, varscan2
- EDIL3 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56896466; called by muse, mutect2, varscan2
- EGFLAM | c.1658G>A p.G553E | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59295524; called by muse, mutect2
- EIF5 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.011); catalogued as rs137964558; called by muse, mutect2, varscan2
- ELOVL3 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.066); catalogued as rs140986921, COSV64174253; called by muse, mutect2, varscan2
- ENSA | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV55026630; called by muse, mutect2, varscan2
- EPYC | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 25/42 reads (60%) | catalogued as rs779578980, COSV53799693; called by muse, mutect2, varscan2
- ERC1 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61694828; called by muse, mutect2, varscan2
- ERC2 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55621275; called by muse, mutect2, varscan2
- ERICH3 | c.2752G>A p.E918K | Missense Mutation (SNP) | VAF 308/469 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV58600178; called by muse, mutect2, varscan2
- ERICH3 | c.2378G>A p.G793E | Missense Mutation (SNP) | VAF 136/228 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs764527597, COSV58605360, COSV58606466; called by muse, mutect2, varscan2
- ERO1B | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142995196; called by muse, mutect2, varscan2
- ESPL1 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs539894607, COSV57758617; called by muse, mutect2, varscan2
- ESPL1 | c.6061C>T p.R2021W | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54475918; called by muse, mutect2, varscan2
- EZH2 | c.1598C>T p.S533L (on ENST00000460911 / NM_001203247.2; = p.S538L on NM_004456.5) | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV57446300; called by muse, mutect2, varscan2
- F13B | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 113/186 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV66373638; called by muse, mutect2, varscan2
- FABP9 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.29); catalogued as rs749835352, COSV66911575; called by muse, mutect2, varscan2
- FAM184A | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.566); catalogued as COSV58854308; called by muse, mutect2, varscan2
- FAM193B | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV61557317; called by muse, mutect2, varscan2
- FAM221B | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as COSV52414147; called by muse, mutect2, varscan2
- FAM71D | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV61295319; called by muse, mutect2, varscan2
- FAT1 | c.6412A>T p.K2138* | Nonsense Mutation (SNP) | VAF 87/132 reads (66%) | catalogued as COSV71673344, COSV71673836; called by muse, mutect2, varscan2
- FAT2 | c.1355A>G p.N452S | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55819538; called by muse, mutect2, varscan2
- FBLN5 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.999); catalogued as COSV50903550; called by muse, mutect2, varscan2
- FCER1A | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 61/95 reads (64%) | catalogued as COSV63667215; called by muse, mutect2, varscan2
- FCGBP | c.7882C>T p.P2628S | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.037); catalogued as rs1387916446; called by muse, mutect2
- FCRL1 | c.109A>G p.T37A | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV63825125; called by muse, mutect2, varscan2
- FHOD1 | c.3324G>A p.M1108I | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV50760813; called by muse, mutect2, varscan2
- FHOD3 | c.4232C>T p.A1411V (on ENST00000359247 / NM_001281739.3; = p.A1428V on NM_025135.5) | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs897426251, COSV57173059; called by muse, mutect2, varscan2
- FITM1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs750767264, COSV52824152; called by muse, mutect2, varscan2
- FOXF1 | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs1457643740, COSV52286097; called by muse, mutect2, varscan2
- FOXN4 | c.1111C>T p.L371F | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.367); catalogued as COSV54494032; called by muse, mutect2, varscan2
- FRAS1 | c.5436G>A p.M1812I | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV53609617, COSV53619992; called by muse, mutect2, varscan2
- FUBP1 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 98/154 reads (64%) | SIFT tolerated (0.25); PolyPhen benign (0.054); catalogued as COSV53930965; called by muse, mutect2, varscan2
- FYB1 | c.1852C>T p.P618S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.335); catalogued as COSV60946148; called by muse, mutect2, varscan2
- GAK | c.876C>T p.I292= | Splice Region (SNP) | VAF 32/49 reads (65%) | catalogued as rs759709734, COSV58504617; called by muse, mutect2, varscan2
- GARNL3 | c.2917C>T p.P973S | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV59226222; called by muse, mutect2, varscan2
- GATM | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV101188257; called by muse, mutect2, varscan2
- GBP5 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58592732, COSV58593360; called by muse, mutect2, varscan2
- GCN1 | c.5257C>T p.R1753* | Nonsense Mutation (SNP) | VAF 94/184 reads (51%) | catalogued as COSV56107625, COSV56109584; called by muse, mutect2, varscan2
- GEMIN5 | c.608G>A p.W203* | Nonsense Mutation (SNP) | VAF 66/133 reads (50%) | catalogued as COSV53560518; called by muse, mutect2, varscan2
- GPC1 | c.416G>A p.R139K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV50863363; called by muse, mutect2, varscan2
- GPR149 | c.1708C>T p.L570F | Missense Mutation (SNP) | VAF 94/201 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67667066; called by muse, mutect2, varscan2
- GRIA1 | c.2213G>A p.G738E | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53592043, COSV53602494; called by muse, mutect2, varscan2
- GRIK2 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 23/101 reads (23%) | catalogued as COSV59735363; called by muse, mutect2, varscan2
- GRIN2B | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.158); catalogued as COSV74205881; called by muse, mutect2, varscan2
- GRM6 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs757015538, COSV51440829, COSV99179415; called by muse, mutect2, varscan2
- GTF2H4 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758320282, COSV52558292; called by muse, mutect2, varscan2
- GUCY2F | c.3166G>A p.E1056K | Missense Mutation (SNP) | VAF 102/118 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV54301351; called by muse, mutect2, varscan2
- HAT1 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs183492276, COSV51362568; called by muse, mutect2, varscan2
- HCAR1 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs373721601; called by muse, mutect2, varscan2
- HDAC10 | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.029); catalogued as COSV50545092; called by muse, mutect2, varscan2
- HDC | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV51068362; called by muse, mutect2, varscan2
- HDC | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99984038; called by muse, mutect2, varscan2
- HELT | c.218G>C p.G73A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as COSV58819910; called by muse, mutect2
- HGF | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV55947254; called by muse, mutect2, varscan2
- HHIPL2 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 130/207 reads (63%) | SIFT tolerated (0.53); PolyPhen benign (0.078); catalogued as rs762718976, COSV58565111; called by muse, mutect2, varscan2
- HOXA4 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs1319460075, COSV57826348; called by muse, mutect2, varscan2
- HOXC12 | c.176A>C p.E59A | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.637); catalogued as COSV54534966; called by muse, mutect2, varscan2
- HRNR | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 243/377 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV64257805; called by muse, mutect2, varscan2
- HSPA1L | c.1742C>T p.S581L | Missense Mutation (SNP) | VAF 81/151 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.228); catalogued as rs371717441; called by muse, mutect2, varscan2
- HUS1 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 88/176 reads (50%) | catalogued as COSV51839430; called by muse, mutect2, varscan2
- IBTK | c.1780C>T p.L594F | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.343); catalogued as COSV60392802; called by muse, mutect2, varscan2
- IGF2R | c.2728T>C p.C910R | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63629044; called by muse, mutect2, varscan2
- IGLL1 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.923); catalogued as COSV50769921; called by muse, mutect2, varscan2
- ILK | c.200A>G p.D67G | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT tolerated (0.28); PolyPhen benign (0.184); catalogued as COSV54449549; called by muse, mutect2, varscan2
- INAVA | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs1557970737, COSV66256554; called by muse, mutect2, varscan2
- IQCF1 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 75/312 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV58823420; called by muse, mutect2, varscan2
- IQCH | c.2186G>A p.W729* | Nonsense Mutation (SNP) | VAF 28/50 reads (56%) | catalogued as COSV60049534; called by muse, mutect2, varscan2
- IRAK2 | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as COSV56531366; called by muse, mutect2, varscan2
- KAT2B | c.833A>T p.Y278F | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55429206; called by muse, mutect2, varscan2
- KCNB2 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.627); catalogued as rs1163367178, COSV73050155; called by muse, mutect2, varscan2
- KCND2 | c.1862G>A p.G621E | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.055); catalogued as COSV58579593; called by muse, mutect2, varscan2
- KCNJ14 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs532186279, COSV60737950; called by muse, mutect2, varscan2
- KCNN4 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.239); catalogued as COSV53455469; called by muse, mutect2, varscan2
- KDM5A | c.2315A>C p.D772A | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.069); catalogued as COSV66992308; called by muse, mutect2, varscan2
- KIAA1217 | c.5270G>A p.R1757K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56816524; called by muse, mutect2, varscan2
- KIAA1522 | c.1325C>T p.P442L (on ENST00000373480 / NM_001198972.2; = p.P501L on NM_020888.3) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1381268568, COSV53864389; called by muse, mutect2, varscan2
- KNG1 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs746309243, COSV53977273; called by muse, mutect2, varscan2
- KRT35 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.248); catalogued as COSV55844024; called by muse, mutect2, varscan2
- LAMA1 | c.2940T>G p.C980W | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67536821; called by muse, mutect2, varscan2
- LAMA5 | c.690C>T p.I230= | Splice Region (SNP) | VAF 8/22 reads (36%) | catalogued as rs371953116; called by muse, mutect2, varscan2
- LCN10 | c.127T>C p.F43L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.94); catalogued as COSV57910316; called by muse, mutect2
- LIPN | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV68383970; called by muse, mutect2, varscan2
- LIX1 | c.515G>A p.W172* | Nonsense Mutation (SNP) | VAF 46/91 reads (51%) | catalogued as COSV57206895; called by muse, mutect2, varscan2
- LPIN2 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as rs868539717, COSV55239679; called by muse, mutect2, varscan2
- LRFN5 | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 79/135 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53255753, COSV53262822; called by muse, mutect2, varscan2
- LRP2 | c.10702C>T p.P3568S | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.097); catalogued as COSV55552720; called by muse, mutect2, varscan2
- LRRC8D | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 63/299 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV61579172; called by muse, mutect2, varscan2
- LUZP2 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 87/122 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV61203756; called by muse, mutect2, varscan2
- MACF1 | c.9503C>T p.S3168F | Missense Mutation (SNP) | VAF 43/184 reads (23%) | catalogued as COSV57120627, COSV57139700; called by muse, mutect2, varscan2
- MAP3K9 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67121260; called by muse, mutect2, varscan2
- MEPE | c.361A>C p.T121P | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as COSV100734952; called by muse, mutect2, varscan2
- MEPE | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.257); catalogued as COSV100734953; called by muse, mutect2, varscan2
- MGAM | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 103/188 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV72074620; called by muse, mutect2, varscan2
- MINAR1 | c.2553G>A p.Q851= | Splice Region (SNP) | VAF 13/48 reads (27%) | catalogued as COSV59582980; called by muse, varscan2
- MKX | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65391852; called by muse, mutect2, varscan2
- MROH2B | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.961); catalogued as rs771053680, COSV68183965; called by muse, mutect2, varscan2
- MSH2 | c.2272G>A p.D758N | Missense Mutation (SNP) | VAF 129/241 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs876658254, COSV51879119; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC16 | c.22181C>T p.S7394F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.991); catalogued as COSV101198802, COSV67465147; called by muse, mutect2
- MUC16 | c.16166C>T p.T5389I | Missense Mutation (SNP) | VAF 165/332 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV67465163; called by muse, mutect2, varscan2
- MUC5B | c.9386C>T p.P3129L | Missense Mutation (SNP) | VAF 68/96 reads (71%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs377732364; called by muse, mutect2, varscan2
- MYH13 | c.3122C>T p.S1041F | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as rs1356172170, COSV52828446; called by muse, mutect2, varscan2
- MYH13 | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 79/112 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as rs745887043, COSV52828463; called by muse, mutect2, varscan2
- MYH15 | c.4961C>T p.S1654F | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); catalogued as COSV56307805; called by muse, mutect2, varscan2
- MYH2 | c.4435G>A p.E1479K | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV55438090; called by muse, mutect2, varscan2
- MYH2 | c.2477C>T p.S826F | Missense Mutation (SNP) | VAF 88/113 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV55438104, COSV99820746; called by muse, mutect2, varscan2
- MYH7 | c.310A>G p.N104D | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV62519127; called by muse, mutect2, varscan2
- MYLK4 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV51141070; called by muse, mutect2, varscan2
- MYRIP | c.2345G>A p.R782Q | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as rs752170706, COSV56868797; called by muse, mutect2, varscan2
- NBAS | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs370943197; called by muse, mutect2, varscan2
- NBEA | c.6239G>A p.R2080Q | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371492100; called by muse, mutect2, varscan2
- NBEAL1 | c.7792G>A p.E2598K | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV68916058; called by muse, mutect2, varscan2
- NCKAP5 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs758470126, COSV58443225; called by muse, mutect2, varscan2
- NDUFA10 | c.170G>C p.S57T | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV53154196, COSV53154933; called by muse, mutect2, varscan2
- NFATC4 | c.2456C>T p.S819F | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as COSV51602280; called by muse, mutect2, varscan2
- NIBAN1 | c.445A>G p.K149E | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV62284665; called by muse, mutect2, varscan2
- NKAIN3 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as rs201185620, COSV60659818; called by muse, mutect2, varscan2
- NOP56 | c.1157C>A p.S386Y | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61389925; called by muse, mutect2, varscan2
- NOS1 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.062); catalogued as COSV57609657; called by muse, mutect2, varscan2
- NOS1AP | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV62634827; called by muse, mutect2, varscan2
- NPAP1 | c.755T>C p.L252P | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.097); catalogued as COSV61506890; called by muse, mutect2, varscan2
- NYAP2 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.997); catalogued as rs761168029, COSV56001990; called by muse, mutect2, varscan2
- OBSCN | c.11129G>A p.R3710K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV52773159; called by muse, mutect2, varscan2
- ONECUT2 | c.60G>A p.M20I | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV72203373; called by muse, mutect2, varscan2
- OR10K1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 228/331 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs188612034, COSV56870795, COSV56872483; called by muse, mutect2, varscan2
- OR1J2 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.009); catalogued as COSV58944370; called by muse, mutect2, varscan2
- OR2A2 | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 81/257 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs576201181, COSV68871576; called by muse, mutect2, varscan2
- OR2L2 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 255/407 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs775471331, COSV63552712; called by muse, mutect2, varscan2
- OR4C12 | c.163T>C p.S55P | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.836); catalogued as COSV58859956; called by muse, mutect2, varscan2
- OR4L1 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 131/230 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs764283168, COSV59849738; called by muse, mutect2, varscan2
- OR51A4 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 131/285 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV66749047; called by muse, mutect2, varscan2
- OR5C1 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs753841911, COSV65456127; called by muse, mutect2, varscan2
- OR5H14 | c.816G>A p.M272I | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as rs753877338, COSV71193761; called by muse, mutect2, varscan2
- OR6C3 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.367); catalogued as rs1324669219, COSV65570683; called by muse, mutect2, varscan2
- OTOGL | c.4447G>A p.D1483N (on ENST00000547103; = p.D1474N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV54016650; called by muse, mutect2, varscan2
- OTOS | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.64); catalogued as rs775327504, COSV56228141; called by muse, mutect2, varscan2
- P2RY10 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 106/122 reads (87%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV50680881, COSV50681309; called by muse, mutect2, varscan2
- P4HB | c.729G>A p.Q243= | Splice Region (SNP) | VAF 62/194 reads (32%) | catalogued as rs1320911660, COSV58941150; called by muse, mutect2, varscan2
- PCBP2 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63728665; called by muse, mutect2, varscan2
- PCBP3 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68407963; called by muse, mutect2, varscan2
- PCBP3 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68407894; called by muse, mutect2, varscan2
- PCDH15 | c.4912G>A p.E1638K | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs867754850, COSV57309177; called by muse, mutect2, varscan2
- PCDHA1 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 74/142 reads (52%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.197); catalogued as rs143010606, COSV65373538; called by muse, mutect2, varscan2
- PCDHA4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 61/134 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.626); catalogued as rs1193581324, COSV63541300; called by muse, mutect2, varscan2
- PCDHA4 | c.1991C>T p.T664I | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as COSV63541306; called by muse, mutect2, varscan2
- PCLO | c.12131G>A p.R4044Q | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271626427, COSV61619046; called by muse, mutect2, varscan2
- PCLO | c.6524C>T p.S2175F | Missense Mutation (SNP) | VAF 79/130 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs868458714, COSV61634661; called by muse, mutect2, varscan2
- PCLO | c.5309T>A p.I1770N | Missense Mutation (SNP) | VAF 79/247 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61634674; called by muse, mutect2, varscan2
- PDE11A | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV53694466; called by muse, mutect2, varscan2
- PDE1A | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs758316258, COSV59522837, COSV59523042; called by muse, mutect2, varscan2
- PDE1C | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV58511357; called by muse, mutect2, varscan2
- PER3 | c.870-1G>A p.X290_splice | Splice Site (SNP) | VAF 98/142 reads (69%) | catalogued as COSV62705807; called by muse, mutect2, varscan2
- PGK2 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV59163832; called by muse, mutect2, varscan2
- PGLYRP4 | c.48G>A p.W16* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV62835256; called by muse, mutect2, varscan2
- PHYHIPL | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.301); catalogued as COSV65848620; called by muse, mutect2, varscan2
- PI4KA | c.4655C>T p.P1552L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55404034; called by muse, mutect2, varscan2
- PIK3AP1 | c.2261T>G p.V754G | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV59532382; called by muse, mutect2, varscan2
- PIPOX | c.586A>T p.K196* | Nonsense Mutation (SNP) | VAF 84/155 reads (54%) | catalogued as COSV60141682; called by muse, mutect2, varscan2
- PKD1L1 | c.5531C>T p.S1844F | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56964640; called by muse, mutect2, varscan2
- PKHD1 | c.4420G>A p.G1474R | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as COSV61874972; called by muse, mutect2, varscan2
- PKHD1L1 | c.2224C>T p.P742S | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs867463123, COSV65742786; called by muse, mutect2, varscan2
- PLCB4 | c.2326G>A p.D776N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53801472; called by muse, mutect2, varscan2
- PLCE1 | c.2195C>T p.S732F | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV53350026; called by muse, mutect2, varscan2
- PLCXD3 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.899); catalogued as COSV60608607; called by muse, mutect2, varscan2
- PLEKHA4 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs763668060, COSV99612584; called by muse, mutect2, varscan2
- PLEKHG2 | c.4138C>T p.P1380S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.132); catalogued as rs1228636695, COSV52682726; called by muse, mutect2, varscan2
- PNP | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs544510557, COSV100828979, COSV64091962; called by muse, mutect2, varscan2
- PODNL1 | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV54308619; called by muse, mutect2, varscan2
- POGLUT3 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 74/105 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60212656; called by muse, mutect2, varscan2
- POLG | c.1182G>T p.Q394H | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.365); catalogued as COSV51521522; called by muse, mutect2, varscan2
- POLR3A | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); catalogued as COSV64931010; called by muse, mutect2, varscan2
- POLR3A | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV64931013; called by muse, mutect2, varscan2
- PPP1R14C | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.569); catalogued as COSV63174108; called by muse, mutect2, varscan2
- PRDM16 | c.3739C>T p.H1247Y | Missense Mutation (SNP) | VAF 55/270 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV54589867; called by muse, mutect2, varscan2
- PREX2 | c.4219C>T p.L1407F | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55761761, COSV55769145, COSV99910499; called by muse, mutect2, varscan2
- PROM2 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.248); catalogued as COSV58298020; called by muse, mutect2
- PSG4 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 128/216 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs769167488, COSV54935644; called by muse, mutect2, varscan2
- PSMB7 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV52330589; called by muse, mutect2
- PTCHD3 | c.926G>A p.S309N | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.185); catalogued as rs749112043, COSV101438909; called by mutect2, varscan2
- PTK7 | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57848571; called by muse, mutect2, varscan2
- PTPN6 | c.131G>A p.R44K | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV59684482; called by muse, mutect2, varscan2
- PTPRZ1 | c.3836C>T p.S1279F | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); catalogued as COSV101099440, COSV66433205; called by muse, mutect2, varscan2
- R3HCC1L | c.1039C>T p.H347Y | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs1424170872, COSV54401081; called by muse, mutect2
- R3HDM1 | c.2236C>T p.H746Y | Missense Mutation (SNP) | VAF 60/201 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV51524624; called by muse, varscan2
- RAB27B | c.462A>T p.K154N | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs763749981, COSV50494804; called by muse, mutect2, varscan2
- RABGGTA | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV52863107; called by muse, mutect2, varscan2
- RACK1 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1399549323, COSV59319031; called by muse, mutect2, varscan2
- RAD54B | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs780128897, COSV60249655; called by muse, mutect2, varscan2
- RANBP17 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV66650011; called by muse, mutect2, varscan2
- RAPGEF4 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 98/226 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV99910668; called by muse, mutect2, varscan2
- RAPGEF4 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 98/227 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs375512263; called by muse, mutect2, varscan2
- RBM45 | c.271C>T p.L91F | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99617717; called by muse, mutect2, varscan2
- RBM46 | c.947G>A p.R316K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as rs1449807176, COSV55978766; called by muse, mutect2, varscan2
- RCSD1 | c.231A>T p.K77N | Missense Mutation (SNP) | VAF 133/212 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63258820; called by muse, mutect2, varscan2
- RFX6 | c.2642C>T p.S881F | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as rs1220624870, COSV60584894; called by muse, mutect2, varscan2
- RIPK4 | c.1577C>T p.A526V (on ENST00000352483; = p.A478V on NM_020639.3) | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV60185865; called by muse, mutect2, varscan2
- RNF19A | c.16A>T p.I6L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV61993138; called by muse, mutect2, varscan2
- ROS1 | c.6803A>C p.N2268T | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as rs1187748126, COSV63855088; called by muse, mutect2, varscan2
- RPAP3 | c.950T>C p.L317P | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV50041768; called by muse, mutect2, varscan2
- RPN2 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.338); catalogued as COSV52905473; called by muse, mutect2, varscan2
- RPS18 | c.41G>T p.R14L | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV71403488; called by muse, mutect2, varscan2
- RSPH10B2 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 51/265 reads (19%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.483); catalogued as COSV99786189; called by muse, mutect2, varscan2
- RTN3 | c.2839C>G p.R947G (on ENST00000377819 / NM_001265589.2; = p.R151G on NM_006054.4) | Missense Mutation (SNP) | VAF 124/180 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58028471, COSV58028642; called by muse, mutect2, varscan2
- RTTN | c.6501G>A p.W2167* | Nonsense Mutation (SNP) | VAF 37/98 reads (38%) | catalogued as COSV55344716; called by muse, mutect2, varscan2
- RYR2 | c.2569C>G p.L857V | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV63685005; called by muse, mutect2, varscan2
- S1PR1 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 155/250 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV59513241; called by muse, mutect2, varscan2
- SAP130 | c.2173C>T p.P725S | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.998); catalogued as COSV52097122; called by muse, mutect2, varscan2
- SCLT1 | c.1357T>C p.F453L | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV55405673, COSV55413861; called by muse, mutect2
- SCN10A | c.299C>T p.T100I | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.864); catalogued as rs758035498, COSV71861314; called by muse, mutect2, varscan2
- SCN2A | c.2792C>T p.S931F | Missense Mutation (SNP) | VAF 85/274 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51840779; called by muse, mutect2, varscan2
- SCN2A | c.5921C>T p.S1974L | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51840801; called by muse, mutect2, varscan2
- SCNN1A | c.539T>C p.L180P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.876); catalogued as COSV57435427; called by muse, mutect2, varscan2
- SEC31B | c.2294C>T p.P765L | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs765043142, COSV64844339; called by muse, mutect2, varscan2
- SERPINA11 | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV58241856; called by muse, mutect2, varscan2
- SERPINA3 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.567); catalogued as rs902226812, COSV67586119; called by muse, mutect2, varscan2
- SERPINB4 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61984761; called by muse, mutect2, varscan2
- SETBP1 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs937896107, COSV56321755; called by muse, mutect2, varscan2
- SETD2 | c.5935C>T p.P1979S | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100338958, COSV57437473; called by muse, varscan2
- SF3B1 | c.988G>T p.G330* | Nonsense Mutation (SNP) | VAF 46/124 reads (37%) | catalogued as COSV59213791; called by muse, mutect2, varscan2
- SFMBT2 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62807399; called by muse, mutect2, varscan2
- SIRPD | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV67546587; called by muse, mutect2, varscan2
- SIRPG | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.248); catalogued as COSV53807362, COSV53810453; called by muse, mutect2, varscan2
- SIRT3 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs762910775, COSV61500998; called by muse, mutect2, varscan2
- SLC22A14 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV56197674; called by muse, mutect2, varscan2
- SLC35F3 | c.233C>T p.S78F (on ENST00000366617 / NM_001300845.1; = p.S147F on NM_173508.4) | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.186); catalogued as COSV64019600; called by muse, mutect2, varscan2
- SLC4A9 | c.2353G>A p.A785T (on ENST00000507527 / NM_001258428.2; = p.A761T on NM_031467.3) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as COSV50189675; called by muse, mutect2, varscan2
- SLC6A18 | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57251233; called by muse, mutect2, varscan2
- SLC7A10 | c.983G>C p.G328A | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV53503926; called by muse, mutect2, varscan2
- SLCO1C1 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV56872448; called by muse, mutect2, varscan2
- SLIT2 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); catalogued as rs139887501; called by muse, mutect2, varscan2
- SLIT2 | c.3745G>A p.D1249N | Missense Mutation (SNP) | VAF 95/144 reads (66%) | SIFT tolerated (0.61); PolyPhen benign (0.159); catalogued as COSV56572020; called by muse, mutect2, varscan2
- SPEG | c.4312G>A p.E1438K | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV56668621; called by muse, mutect2, varscan2
- SPHKAP | c.3379G>A p.D1127N | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs753808266, COSV60878434; called by muse, mutect2, varscan2
- SPHKAP | c.2861G>A p.G954E | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60868618; called by muse, mutect2, varscan2
- SPPL2B | c.372C>T p.V124= | Splice Region (SNP) | VAF 16/29 reads (55%) | catalogued as rs373935067, COSV66316854; called by muse, mutect2, varscan2
- SPTB | c.5440G>A p.D1814N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1193527563, COSV67629626, COSV67631738; called by muse, mutect2, varscan2
- STAB1 | c.7432G>A p.A2478T | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1223375477, COSV100195034; called by muse, mutect2, varscan2
- STAB2 | c.3038G>A p.W1013* | Nonsense Mutation (SNP) | VAF 80/130 reads (62%) | catalogued as COSV66338805; called by muse, mutect2, varscan2
- STK17A | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as rs1233707345, COSV60047076; called by muse, mutect2
- STPG2 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 28/141 reads (20%) | catalogued as COSV54797550; called by muse, mutect2, varscan2
- SUDS3 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as COSV66916147; called by muse, mutect2, varscan2
- SUPT16H | c.1193C>T p.T398I | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as COSV53524520; called by muse, mutect2, varscan2
- SYNGR2 | c.257T>C p.L86S | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs373723886; called by muse, mutect2
- SYT5 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV62830312; called by muse, mutect2, varscan2
- TAFA1 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV72038472; called by muse, mutect2, varscan2
- TAMALIN | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV53337792; called by muse, mutect2, varscan2
- TBC1D8 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as rs373248214; called by muse, mutect2, varscan2
- TBC1D9 | c.3740G>A p.R1247Q | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as rs767747261, COSV71307472; called by muse, mutect2, varscan2
- TCAF1 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV63518140; called by muse, mutect2, varscan2
- TCHHL1 | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 284/451 reads (63%) | SIFT tolerated (0.48); PolyPhen benign (0.166); catalogued as COSV64285697; called by muse, mutect2, varscan2
- TDRD6 | c.1720A>T p.N574Y | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60175660; called by muse, mutect2, varscan2
- TEX2 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 109/309 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); catalogued as COSV51980876; called by muse, mutect2, varscan2
- TEX26 | c.469+2T>A p.X157_splice | Splice Site (SNP) | VAF 28/52 reads (54%) | catalogued as COSV66839872; called by muse, mutect2, varscan2
- TEX35 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV51104895, COSV51105389; called by muse, mutect2, varscan2
- TEX55 | c.1292A>G p.N431S | Missense Mutation (SNP) | VAF 88/156 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV55211073; called by muse, mutect2, varscan2
- TLR4 | c.1453G>A p.E485K (on ENST00000355622 / NM_138554.5; = p.E445K on NM_003266.4) | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1023995398, COSV62922298; called by muse, varscan2
- TLR8 | c.562G>A p.E188K (on ENST00000218032 / NM_138636.5; = p.E206K on NM_016610.4) | Missense Mutation (SNP) | VAF 63/73 reads (86%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs376034872, COSV54317022; called by muse, mutect2, varscan2
- TMC3 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63923129, COSV63924367; called by muse, mutect2, varscan2
- TMCC3 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 68/124 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777603579, COSV54154362; called by muse, mutect2, varscan2
- TMX3 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV55185364; called by muse, mutect2, varscan2
- TNFRSF14 | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 59/243 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV63186647; called by muse, mutect2, varscan2
- TNIP1 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.776); catalogued as COSV59306566; called by muse, mutect2, varscan2
- TNRC6B | c.2761C>T p.R921* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV57294984; called by muse, mutect2
- TP63 | c.1448A>G p.N483S | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.184); catalogued as rs992044215, COSV53205644; called by muse, mutect2, varscan2
- TP63 | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1360624743, COSV53205667, COSV53221929; called by muse, mutect2, varscan2
- TRAPPC10 | c.2935C>T p.L979F | Missense Mutation (SNP) | VAF 67/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52377264; called by muse, mutect2, varscan2
- TRAV5 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 100/197 reads (51%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs779741225; called by muse, mutect2, varscan2
- TRMT13 | c.1190G>A p.S397N | Missense Mutation (SNP) | VAF 82/346 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV100734459; called by muse, mutect2, varscan2
- TRMT13 | c.1191T>A p.S397R | Missense Mutation (SNP) | VAF 79/347 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.057); catalogued as COSV100734460; called by muse, mutect2, varscan2
- TRPM6 | c.4558C>T p.Q1520* | Nonsense Mutation (SNP) | VAF 30/106 reads (28%) | catalogued as rs1239946434, COSV62506711, COSV62509881; called by muse, mutect2, varscan2
- TRPV3 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 41/54 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV56791287; called by muse, mutect2, varscan2
- TRRAP | c.5063C>T p.T1688I (on ENST00000359863 / NM_001244580.1; = p.T1670I on NM_003496.3) | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT tolerated (0.27); PolyPhen benign (0.109); catalogued as COSV62844138; called by muse, mutect2, varscan2
- TTC8 | c.401C>T p.T134I (on ENST00000338104 / NM_001288781.1; = p.T144I on NM_144596.4) | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100581342; called by muse, mutect2, varscan2
- TTLL11 | c.1088C>T p.T363I | Missense Mutation (SNP) | VAF 75/140 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV58646275; called by muse, mutect2, varscan2
- TTN | c.101800G>A p.E33934K (on ENST00000591111; = p.E26510K on NM_003319.4) | Missense Mutation (SNP) | VAF 43/82 reads (52%) | PolyPhen benign (0); catalogued as rs886055217, COSV60052141; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.62339G>A p.G20780E (on ENST00000591111; = p.G13356E on NM_003319.4) | Missense Mutation (SNP) | VAF 101/197 reads (51%) | PolyPhen probably damaging (1); catalogued as COSV100631007, COSV59942139; called by muse, mutect2, varscan2
- TTN | c.40321G>A p.G13441R (on ENST00000591111; = p.G6017R on NM_003319.4) | Missense Mutation (SNP) | VAF 26/92 reads (28%) | PolyPhen probably damaging (0.992); catalogued as COSV60052324; called by muse, mutect2, varscan2
- TTN | c.21884A>G p.K7295R (on ENST00000591111; = p.K6368R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | PolyPhen probably damaging (0.978); catalogued as COSV60052377; called by muse, mutect2, varscan2
- TTN | c.15805G>A p.E5269K (on ENST00000591111; = p.E4342K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/277 reads (35%) | PolyPhen benign (0.053); catalogued as COSV59911701; called by muse, mutect2, varscan2
- UBP1 | c.1210G>T p.D404Y | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52145630; called by muse, mutect2, varscan2
- UBR5 | c.6310T>C p.Y2104H | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.969); catalogued as COSV55286416; called by muse, mutect2, varscan2
- UGT1A10 | c.807G>A p.M269I | Missense Mutation (SNP) | VAF 278/595 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV60838931; called by muse, mutect2, varscan2
- UGT1A8 | c.169G>T p.V57L | Missense Mutation (SNP) | VAF 96/221 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV65078151; called by muse, mutect2, varscan2
- UGT1A9 | c.307C>G p.R103G | Missense Mutation (SNP) | VAF 84/173 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV60836173, COSV60838942; called by muse, mutect2, varscan2
- UGT3A1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV57098016; called by muse, mutect2, varscan2
- UNC13A | c.3739G>A p.E1247K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.25); catalogued as COSV53195568; called by muse, mutect2, varscan2
- UNC13C | c.5101G>A p.E1701K | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs768039530, COSV52841291, COSV52849785; called by muse, mutect2, varscan2
- UNC5A | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as rs145793659; called by muse, mutect2, varscan2
- USP18 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234574299, COSV99306078; called by muse, mutect2, varscan2
- USP40 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV52480724; called by muse, mutect2, varscan2
- USP5 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99978609; called by muse, mutect2, varscan2
- USP5 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99978613; called by muse, mutect2, varscan2
- USP9Y | c.5998A>G p.M2000V | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV59099478; called by muse, mutect2, varscan2
- VIRMA | c.2968C>T p.H990Y | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV52584950; called by muse, mutect2, varscan2
- VPS37D | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs782256084, COSV61446502; called by muse, mutect2, varscan2
- VPS45 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782677308, COSV64887801; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR26 | c.902C>T p.S301F (on ENST00000414423 / NM_001379403.1; = p.S201F on NM_025160.7) | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT tolerated (0.13); PolyPhen benign (0.161); catalogued as COSV54355376; called by muse, mutect2, varscan2
- WDR59 | c.2168C>T p.P723L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50935412; called by muse, mutect2, varscan2
- WFIKKN2 | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV60958648; called by muse, mutect2, varscan2
- WNK2 | c.3361G>A p.E1121K | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV52941482; called by muse, mutect2, varscan2
- ZC3H12A | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 106/176 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66103917; called by muse, mutect2, varscan2
- ZDBF2 | c.5425G>A p.E1809K | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV65625857; called by muse, mutect2, varscan2
- ZFC3H1 | c.2977G>A p.E993K | Missense Mutation (SNP) | VAF 118/229 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.321); catalogued as COSV66432498; called by muse, mutect2, varscan2
- ZFHX4 | c.3164C>T p.T1055I | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV50696604, COSV50784457; called by muse, mutect2, varscan2
- ZMYM1 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 75/116 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs1409599341, COSV63251865; called by muse, mutect2, varscan2
- ZNF160 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.199); catalogued as COSV100762336; called by muse, mutect2, varscan2
- ZNF197 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV60360508; called by muse, mutect2, varscan2
- ZNF235 | c.1850A>G p.H617R | Missense Mutation (SNP) | VAF 113/212 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52156453; called by muse, mutect2, varscan2
- ZNF239 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.352); catalogued as rs868142686, COSV60018361; called by muse, mutect2, varscan2
- ZNF253 | c.188T>C p.L63S | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs369720954; called by muse, mutect2, varscan2
- ZNF30 | c.1831C>T p.L611F | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.709); catalogued as COSV100340803, COSV57853847; called by muse, mutect2, varscan2
- ZNF333 | c.1241G>A p.R414K | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV52886049, COSV99469524; called by muse, mutect2, varscan2
- ZNF449 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 57/69 reads (83%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs375822943, COSV59346637; called by muse, mutect2, varscan2
- ZNF490 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 72/150 reads (48%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.741); catalogued as rs556545502, COSV61007993; called by muse, mutect2, varscan2
- ZNF560 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 99/202 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs149138221, COSV56867070; called by muse, mutect2, varscan2
- ZNF566 | c.889A>G p.N297D | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as rs868854268, COSV67573689; called by muse, mutect2, varscan2
- ZNF613 | c.610C>T p.H204Y (on ENST00000293471 / NM_001031721.4; = p.H168Y on NM_024840.4) | Missense Mutation (SNP) | VAF 63/350 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.044); catalogued as COSV53271720; called by muse, mutect2, varscan2
- ZNF677 | c.124A>G p.R42G | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV61720248; called by muse, mutect2, varscan2
- ZNF678 | c.1442G>A p.R481K | Missense Mutation (SNP) | VAF 72/117 reads (62%) | SIFT tolerated (0.42); PolyPhen benign (0.059); catalogued as COSV59382816, COSV59385009, COSV59386584; called by muse, mutect2, varscan2
- ZSCAN1 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs769617673, COSV56604373; called by muse, mutect2, varscan2
- CCDC125 | c.331_343del p.E111Nfs*7 | Frame Shift Del (DEL) | VAF 59/145 reads (41%) | called by mutect2, pindel, varscan2
- CSAG3 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- FBXO17 | c.447_449del p.F149_V150delinsL | In Frame Del (DEL) | VAF 21/60 reads (35%) | called by mutect2, pindel, varscan2
- MRC1 | c.1551G>A p.M517I | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NARF | c.608del p.S203Ffs*3 | Frame Shift Del (DEL) | VAF 31/64 reads (48%) | called by mutect2, pindel, varscan2
- POTEF | c.1556G>A p.R519K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); called by mutect2, varscan2
- PRPF6 | c.1958C>T p.S653F | Missense Mutation (SNP) | VAF 100/259 reads (39%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- RBP3 | c.1913C>T p.A638V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZC3H3 | c.885_894del p.S296* | Frame Shift Del (DEL) | VAF 16/130 reads (12%) | called by mutect2, pindel
- ZNF236 | c.1111_1128del p.E371_P376del | In Frame Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- ZNF320 | c.609_610insAT p.L204Ifs*87 | Frame Shift Ins (INS) | VAF 14/92 reads (15%) | called by pindel, varscan2
- AARS2 | c.1605G>A p.V535= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV55114711, COSV55115754; called by muse, mutect2, varscan2
- ABCA2 | c.5235C>T p.A1745= (on ENST00000614293; = p.A1715= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV55801069; called by muse, mutect2, varscan2
- ABCA4 | c.6168G>A p.K2056= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV64673448; called by muse, mutect2, varscan2
- ABCA6 | c.696C>T p.S232= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as COSV52638562; called by muse, mutect2, varscan2
- ABCA8 | c.2079C>T p.I693= | Silent (SNP) | VAF 45/80 reads (56%) | catalogued as COSV52201066; called by muse, mutect2, varscan2
- ABCC8 | c.396C>T p.F132= | Silent (SNP) | VAF 36/46 reads (78%) | catalogued as COSV56850338; called by muse, mutect2, varscan2
- ABCE1 | c.625C>T p.L209= | Silent (SNP) | VAF 58/104 reads (56%) | catalogued as COSV56847147; called by muse, mutect2, varscan2
- ACAD10 | c.21C>T p.F7= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV58156664; called by muse, mutect2, varscan2
- ACAN | c.2391G>A p.E797= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV61360219; called by muse, mutect2
- ACTN1 | c.951G>A p.R317= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV51991652; called by muse, mutect2, varscan2
- ADGRL1 | c.3270G>A p.G1090= (on ENST00000340736 / NM_001008701.3; = p.G1085= on NM_014921.5) | Silent (SNP) | VAF 46/102 reads (45%) | catalogued as rs761920179, COSV61564669; called by muse, mutect2, varscan2
- AGFG2 | c.642C>T p.P214= | Silent (SNP) | VAF 62/105 reads (59%) | catalogued as COSV53545113; called by muse, mutect2, varscan2
- AJM1 | c.912C>T p.A304= | Silent (SNP) | VAF 29/44 reads (66%) | catalogued as COSV56032971; called by muse, mutect2, varscan2
- ANGEL2 | c.822C>T p.F274= | Silent (SNP) | VAF 38/213 reads (18%) | catalogued as COSV64737371; called by muse, mutect2, varscan2
- ANK1 | c.2613G>A p.V871= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV55881353; called by muse, mutect2, varscan2
- ANKRD30A | c.3348G>A p.L1116= (on ENST00000611781; = p.L1060= on NM_052997.2) | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as COSV64609968; called by muse, mutect2, varscan2
- AP3M2 | c.222C>T p.V74= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV51528744; called by muse, mutect2, varscan2
- AP5B1 | c.1578G>A p.V526= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV57502930; called by muse, mutect2, varscan2
- ARFGEF1 | c.5481T>C p.F1827= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV51584328; called by muse, mutect2, varscan2
- ARHGAP33 | c.2148C>T p.P716= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs912367151, COSV50123213; called by muse, mutect2, varscan2
- ARHGAP45 | c.1737C>T p.F579= | Silent (SNP) | VAF 52/109 reads (48%) | catalogued as COSV57431792; called by muse, mutect2, varscan2
- ARNTL2 | c.915G>A p.K305= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV53825746; called by muse, mutect2, varscan2
- ATP10B | c.933G>A p.R311= | Silent (SNP) | VAF 40/169 reads (24%) | catalogued as COSV58778738; called by muse, mutect2, varscan2
- ATP7B | c.3816C>T p.S1272= | Silent (SNP) | VAF 49/61 reads (80%) | catalogued as COSV54438302; called by muse, mutect2, varscan2
- AXL | c.1050C>T p.F350= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs1438536181, COSV56565671; called by muse, mutect2, varscan2
- BEND7 | c.94C>T p.L32= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV61988929; called by muse, mutect2, varscan2
- BNC1 | c.1014C>T p.S338= | Silent (SNP) | VAF 46/97 reads (47%) | catalogued as COSV61757396; called by muse, mutect2, varscan2
- C16orf89 | c.567G>A p.K189= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as COSV60123712; called by muse, mutect2, varscan2
- CADPS | c.2232C>T p.I744= | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as COSV51868659, COSV51903037; called by muse, mutect2, varscan2
- CAPN9 | c.72C>T p.S24= | Silent (SNP) | VAF 92/154 reads (60%) | catalogued as COSV55233538; called by muse, mutect2, varscan2
- CAPZA3 | c.165C>T p.H55= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as COSV56852525, COSV99856060; called by muse, mutect2, varscan2
- CCDC191 | c.66G>C p.R22= | Silent (SNP) | VAF 54/137 reads (39%) | catalogued as COSV55559964; called by muse, mutect2, varscan2
- CCDC33 | c.1152C>T p.P384= | Silent (SNP) | VAF 42/81 reads (52%) | catalogued as COSV58351705; called by muse, mutect2, varscan2
- CCNA2 | c.627T>C p.S209= | Silent (SNP) | VAF 88/151 reads (58%) | catalogued as COSV52656487; called by muse, mutect2, varscan2
- CD200R1L | c.558C>T p.Y186= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV68004248; called by muse, mutect2, varscan2
- CDH18 | c.2173C>T p.L725= | Silent (SNP) | VAF 37/81 reads (46%) | catalogued as COSV56921091; called by muse, mutect2, varscan2
- CDH23 | c.2373C>T p.T791= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV54933879; called by muse, mutect2, varscan2
- CEACAM19 | c.756C>T p.S252= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV62551987; called by muse, mutect2, varscan2
- CELF1 | c.477C>T p.A159= | Silent (SNP) | VAF 94/143 reads (66%) | catalogued as COSV60111972; called by muse, mutect2, varscan2
- CEMIP2 | c.954C>T p.A318= | Silent (SNP) | VAF 79/148 reads (53%) | catalogued as rs761361270, COSV65485919; called by muse, mutect2, varscan2
- CFAP46 | c.5704C>T p.L1902= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99584800; called by muse, mutect2, varscan2
- CFAP46 | c.5703C>T p.S1901= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99584804; called by muse, mutect2, varscan2
- CGNL1 | c.2556C>T p.I852= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs778893351, COSV55563313; called by muse, mutect2, varscan2
- CHL1 | c.234C>T p.F78= | Silent (SNP) | VAF 33/143 reads (23%) | catalogued as COSV56593195; called by muse, mutect2, varscan2
- CHRDL1 | c.1140C>T p.L380= (on ENST00000372045; = p.L386= on NM_145234.4) | Silent (SNP) | VAF 46/57 reads (81%) | catalogued as COSV54325036; called by muse, mutect2, varscan2
- CNTN2 | c.3000C>T p.I1000= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as rs947096199, COSV59348045; called by muse, mutect2, varscan2
- CNTNAP4 | c.3234C>T p.I1078= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV56679474; called by muse, mutect2, varscan2
- COL16A1 | c.4764G>A p.P1588= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs746338688, COSV54705562; called by muse, mutect2, varscan2
- COL6A3 | c.3876G>A p.K1292= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV55089034; called by muse, mutect2, varscan2
- CORO2A | c.1050C>T p.I350= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs746789995, COSV59663178; called by muse, mutect2, varscan2
- CRHR1 | c.738C>T p.I246= (on ENST00000398285 / NM_001145146.2; = p.I217= on NM_004382.5) | Silent (SNP) | VAF 96/188 reads (51%) | catalogued as rs769867467, COSV53276871, COSV53278695; called by muse, mutect2, varscan2
- CRYBG1 | c.4866C>T p.F1622= | Silent (SNP) | VAF 32/59 reads (54%) | catalogued as COSV64812075; called by muse, mutect2, varscan2
- CTC1 | c.1980C>T p.I660= | Silent (SNP) | VAF 90/137 reads (66%) | catalogued as rs929139383, COSV59852136; called by muse, mutect2, varscan2
- CWH43 | c.945C>T p.T315= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as COSV99893446; called by muse, mutect2, varscan2
- CYFIP2 | c.1428G>A p.R476= | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as rs1322132941, COSV59037008; called by muse, mutect2, varscan2
- CYP2U1 | c.775C>T p.L259= | Silent (SNP) | VAF 33/197 reads (17%) | catalogued as COSV60548850; called by muse, mutect2, varscan2
- DDX1 | c.1515G>A p.K505= | Silent (SNP) | VAF 50/105 reads (48%) | catalogued as rs1407496851, COSV51839913; called by muse, mutect2, varscan2
- DDX53 | c.1164C>T p.P388= | Silent (SNP) | VAF 156/186 reads (84%) | catalogued as COSV60069019; called by muse, mutect2, varscan2
- DNAH9 | c.12135G>A p.T4045= | Silent (SNP) | VAF 164/238 reads (69%) | catalogued as rs374717515; called by muse, mutect2, varscan2
- DNM1 | c.1116C>T p.F372= | Silent (SNP) | VAF 46/86 reads (53%) | catalogued as rs367584321; ClinVar: likely benign; called by muse, mutect2, varscan2
- DOCK2 | c.2997C>T p.V999= | Silent (SNP) | VAF 30/55 reads (55%) | catalogued as COSV56957971; called by muse, mutect2, varscan2
- DOK6 | c.159C>T p.F53= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV66931009; called by muse, mutect2, varscan2
- EFEMP1 | c.1203A>T p.R401= | Silent (SNP) | VAF 9/127 reads (7%) | catalogued as COSV100816963, COSV62616034; called by muse, mutect2
- EPPK1 | c.354C>T p.A118= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs1175721541, COSV73261226; called by muse, mutect2, varscan2
- ERC2 | c.2535G>A p.R845= | Silent (SNP) | VAF 45/143 reads (31%) | catalogued as rs1426124624, COSV55602966; called by muse, mutect2, varscan2
- FAM135B | c.3519C>T p.F1173= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV52724035; called by muse, mutect2, varscan2
- FAT4 | c.9198G>A p.K3066= | Silent (SNP) | VAF 82/128 reads (64%) | catalogued as COSV100628579, COSV58684442; called by muse, mutect2, varscan2
- FER1L5 | c.4020G>A p.K1340= (on ENST00000623019; = p.K1313= on NM_001293083.2) | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs1281581049, COSV67606170, COSV67606468; called by muse, mutect2, varscan2
- FMN2 | c.4206C>T p.L1402= | Silent (SNP) | VAF 90/143 reads (63%) | catalogued as COSV60429968; called by muse, mutect2, varscan2
- FNDC7 | c.849G>A p.L283= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV54753477; called by muse, mutect2, varscan2
- FSD2 | c.1077G>A p.V359= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV58009989; called by muse, mutect2, varscan2
- FYB1 | c.828C>T p.S276= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as COSV60946176; called by muse, mutect2, varscan2
- FZD2 | c.1119C>T p.H373= | Silent (SNP) | VAF 49/164 reads (30%) | catalogued as COSV59528670; called by muse, mutect2, varscan2
- GATM | c.186G>A p.K62= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV101188258; called by muse, mutect2, varscan2
- GBP2 | c.126G>A p.A42= | Silent (SNP) | VAF 148/228 reads (65%) | catalogued as rs200629962, COSV65069245; called by muse, mutect2, varscan2
- GDA | c.660G>A p.E220= | Silent (SNP) | VAF 50/93 reads (54%) | catalogued as COSV52993056; called by muse, mutect2, varscan2
- GFRA1 | c.978G>A p.L326= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV62605569; called by muse, mutect2, varscan2
- GJB5 | c.438C>T p.L146= | Silent (SNP) | VAF 39/154 reads (25%) | catalogued as COSV58356174; called by muse, mutect2, varscan2
- GPR75 | c.39C>G p.A13= | Silent (SNP) | VAF 43/167 reads (26%) | catalogued as COSV61827160; called by muse, mutect2, varscan2
- GSDMC | c.1197C>T p.L399= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs867988380, COSV52695395; called by muse, mutect2, varscan2
- HAO2 | c.384A>G p.Q128= | Silent (SNP) | VAF 47/217 reads (22%) | catalogued as COSV58039450; called by muse, mutect2, varscan2
- HCN1 | c.2289G>A p.P763= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs759408275, COSV57502023; called by muse, mutect2, varscan2
- HCN1 | c.2178G>A p.Q726= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs1039430806, COSV57510006; called by muse, mutect2, varscan2
- HDC | c.306G>A p.L102= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV51070239; called by muse, mutect2, varscan2
- HERC2 | c.9561G>A p.R3187= | Silent (SNP) | VAF 82/150 reads (55%) | catalogued as COSV55323229; called by muse, mutect2, varscan2
- HNF1A | c.669C>T p.N223= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV57462149, COSV99982734; called by muse, mutect2, varscan2
- HTT | c.9033C>T p.F3011= | Silent (SNP) | VAF 45/76 reads (59%) | catalogued as COSV61861888; called by muse, mutect2, varscan2
- HYDIN | c.5775G>A p.L1925= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV59256961; called by muse, mutect2, varscan2
- HYDIN | c.219G>A p.Q73= | Silent (SNP) | VAF 36/127 reads (28%) | catalogued as COSV55485314; called by muse, mutect2, varscan2
- IFNA14 | c.513C>T p.I171= | Silent (SNP) | VAF 224/340 reads (66%) | catalogued as rs372909491; called by muse, mutect2, varscan2
- IGHV3-21 | c.27C>T p.F9= | Silent (SNP) | VAF 27/162 reads (17%) | catalogued as rs572845523; called by muse, mutect2, varscan2
- IGLV3-27 | c.219C>T p.P73= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs1469912743; called by muse, mutect2, varscan2
- IL17RA | c.1674C>T p.Y558= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs1165004543, COSV60053152; called by muse, mutect2, varscan2
- IL20 | c.273G>A p.L91= | Silent (SNP) | VAF 457/716 reads (64%) | catalogued as COSV65584542; called by muse, mutect2, varscan2
- IL4R | c.2346C>T p.P782= | Silent (SNP) | VAF 54/103 reads (52%) | catalogued as COSV50142961; called by muse, mutect2, varscan2
- ISM1 | c.759G>A p.S253= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as rs1283525883, COSV52604623; called by muse, mutect2, varscan2
- ITGAE | c.2664T>C p.S888= | Silent (SNP) | VAF 29/40 reads (73%) | catalogued as COSV53993717; called by muse, mutect2, varscan2
- ITGB4 | c.3897G>A p.K1299= | Silent (SNP) | VAF 80/250 reads (32%) | catalogued as COSV52325754; called by muse, mutect2, varscan2
- KALRN | c.7170A>G p.A2390= (on ENST00000360013 / NM_001024660.4; = p.A693= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV52256144; called by muse, mutect2, varscan2
- KCNA4 | c.108C>T p.S36= | Silent (SNP) | VAF 53/79 reads (67%) | catalogued as COSV60252139, COSV60254388; called by muse, mutect2, varscan2
- KCNK1 | c.432C>T p.F144= | Silent (SNP) | VAF 72/104 reads (69%) | catalogued as COSV64035075; called by muse, mutect2, varscan2
- KCNK9 | c.519C>T p.I173= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV57281525; called by muse, mutect2, varscan2
- KIN | c.564C>T p.V188= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV65430566; called by muse, mutect2, varscan2
- KLK5 | c.69C>T p.V23= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs968237541, COSV60450299; called by muse, mutect2
- KLRF1 | c.675C>T p.F225= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV54380849; called by muse, mutect2, varscan2
- KRT35 | c.60G>A p.G20= | Silent (SNP) | VAF 42/105 reads (40%) | catalogued as COSV99877779; called by muse, mutect2, varscan2
- KRTAP9-8 | c.264C>T p.S88= | Silent (SNP) | VAF 59/219 reads (27%) | catalogued as COSV54199886; called by muse, mutect2, varscan2
- L1TD1 | c.351G>A p.G117= | Silent (SNP) | VAF 41/241 reads (17%) | catalogued as rs1392135786, COSV63133483; called by muse, mutect2, varscan2
- LARP1B | c.2121T>C p.F707= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs1364856663, COSV52797496; called by muse, mutect2, varscan2
- LARP1B | c.2538C>T p.F846= | Silent (SNP) | VAF 53/97 reads (55%) | catalogued as COSV52797511; called by muse, mutect2, varscan2
- LCT | c.5136C>T p.R1712= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs1171125418, COSV51549092; called by muse, mutect2, varscan2
- LMBR1 | c.453G>A p.L151= | Silent (SNP) | VAF 94/164 reads (57%) | catalogued as COSV62220149, COSV62222969; called by muse, mutect2, varscan2
- LRG1 | c.768C>T p.F256= | Silent (SNP) | VAF 57/221 reads (26%) | catalogued as COSV56703666; called by muse, mutect2, varscan2
- LRP1B | c.1497G>A p.R499= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as COSV67218428, COSV67266573; called by muse, mutect2, varscan2
- LRRC17 | c.180C>T p.L60= | Silent (SNP) | VAF 59/97 reads (61%) | catalogued as COSV50864647; called by muse, mutect2, varscan2
- LRRC20 | c.192C>T p.S64= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs367993352; called by muse, mutect2, varscan2
- MAGI3 | c.513G>T p.L171= | Silent (SNP) | VAF 96/165 reads (58%) | catalogued as COSV56835101; called by muse, mutect2, varscan2
- MAP4K3 | c.2349G>A p.E783= | Silent (SNP) | VAF 64/137 reads (47%) | catalogued as COSV55712992, COSV55718620; called by muse, mutect2, varscan2
- MBD5 | c.3609C>T p.P1203= | Silent (SNP) | VAF 49/182 reads (27%) | catalogued as COSV68696964; called by muse, mutect2, varscan2
- ME1 | c.186C>T p.F62= | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as rs748274488, COSV63838212; called by muse, mutect2, varscan2
- MORC1 | c.2751G>A p.L917= | Silent (SNP) | VAF 32/146 reads (22%) | catalogued as COSV51719759; called by muse, mutect2, varscan2
- MPI | c.1218G>A p.L406= | Silent (SNP) | VAF 42/70 reads (60%) | catalogued as COSV60396784; called by muse, mutect2, varscan2
- MTHFD1L | c.2193C>T p.S731= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as rs747201948, COSV66225278; called by muse, mutect2, varscan2
- MTPAP | c.618C>T p.L206= | Silent (SNP) | VAF 41/114 reads (36%) | catalogued as COSV53932884; called by muse, mutect2, varscan2
- MUC16 | c.21330C>T p.P7110= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV67465154; called by muse, mutect2, varscan2
- MUC16 | c.13224C>T p.T4408= | Silent (SNP) | VAF 35/162 reads (22%) | catalogued as COSV67465172; called by muse, mutect2, varscan2
- MUC2 | c.1575C>T p.F525= | Silent (SNP) | VAF 14/19 reads (74%) | catalogued as rs374772849; called by muse, mutect2, varscan2
- MYH1 | c.2751C>T p.I917= | Silent (SNP) | VAF 95/158 reads (60%) | catalogued as COSV99875208; called by muse, mutect2, varscan2
- MYOF | c.5652C>T p.I1884= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV63704088; called by muse, mutect2, varscan2
- MYPN | c.117C>T p.S39= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs868525033, COSV62733857; called by muse, mutect2, varscan2
- NCKAP1L | c.1332C>T p.I444= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as rs866215180, COSV53206674; called by muse, mutect2, varscan2
- NDUFAF7 | c.756G>A p.L252= | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as COSV50017504; called by muse, mutect2, varscan2
- NES | c.1623G>A p.L541= | Silent (SNP) | VAF 38/197 reads (19%) | catalogued as rs1445740635, COSV63961026; called by muse, mutect2, varscan2
- NLRP2 | c.912C>T p.I304= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV54754973; called by muse, mutect2, varscan2
- NOM1 | c.2079C>A p.L693= | Silent (SNP) | VAF 74/279 reads (27%) | catalogued as COSV51980116; called by muse, mutect2, varscan2
- NOS3 | c.666C>G p.G222= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as COSV52489631, COSV52492172; called by muse, mutect2, varscan2
- NSD1 | c.5439C>T p.F1813= | Silent (SNP) | VAF 58/107 reads (54%) | catalogued as COSV61776125; called by muse, mutect2, varscan2
- NTRK1 | c.321G>A p.A107= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs774351278, COSV62325535; called by muse, varscan2
- ODAM | c.831G>A p.R277= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV68572718; called by muse, mutect2, varscan2
- OR10X1 | c.798C>T p.I266= | Silent (SNP) | VAF 57/275 reads (21%) | catalogued as COSV100936600, COSV63767338; called by muse, mutect2, varscan2
- OR1J1 | c.186C>T p.F62= | Silent (SNP) | VAF 89/181 reads (49%) | catalogued as rs868316892, COSV52238437; called by muse, mutect2, varscan2
- OR2T33 | c.516C>T p.I172= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as rs766081047, COSV58815350, COSV58817061; called by muse, mutect2
- OR51A4 | c.693C>T p.S231= | Silent (SNP) | VAF 53/78 reads (68%) | catalogued as COSV66749440; called by muse, mutect2, varscan2
- OR51B2 | c.442C>T p.L148= | Silent (SNP) | VAF 94/131 reads (72%) | catalogued as COSV60916601; called by muse, varscan2
- OR5J2 | c.138C>T p.I46= | Silent (SNP) | VAF 118/173 reads (68%) | catalogued as COSV56621207; called by muse, mutect2, varscan2
- OR6K6 | c.921C>T p.I307= (on ENST00000368144; = p.I283= on NM_001005184.1) | Silent (SNP) | VAF 31/187 reads (17%) | catalogued as rs767138484, COSV63744148; called by muse, mutect2, varscan2
- OR8G5 | c.312C>T p.F104= | Silent (SNP) | VAF 67/101 reads (66%) | catalogued as COSV100422429; called by muse, mutect2, varscan2
- OTOF | c.861C>T p.S287= | Silent (SNP) | VAF 42/112 reads (38%) | catalogued as COSV55502724; called by muse, mutect2, varscan2
- PACS2 | c.822C>T p.D274= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs1201954528, COSV57652611; called by muse, mutect2, varscan2
- PAPPA | c.2361C>T p.F787= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV100074772, COSV60283076; called by muse, mutect2, varscan2
- PAPPA2 | c.4056C>T p.I1352= | Silent (SNP) | VAF 97/173 reads (56%) | catalogued as COSV62797353; called by muse, mutect2, varscan2
- PCDHB1 | c.1197G>A p.G399= | Silent (SNP) | VAF 43/150 reads (29%) | catalogued as COSV60629509; called by muse, mutect2, varscan2
- PCDHB4 | c.1695G>A p.Q565= | Silent (SNP) | VAF 66/120 reads (55%) | catalogued as COSV52022325; called by muse, mutect2, varscan2
- PCLO | c.6819C>T p.I2273= | Silent (SNP) | VAF 123/218 reads (56%) | catalogued as COSV61634644; called by muse, mutect2, varscan2
- PDE7B | c.861G>A p.Q287= | Silent (SNP) | VAF 70/144 reads (49%) | catalogued as COSV57497000; called by muse, mutect2, varscan2
- PDZD7 | c.525C>T p.S175= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV64646134; called by muse, mutect2, varscan2
- PIGR | c.156G>A p.R52= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as rs1209083440, COSV62903995; called by muse, mutect2, varscan2
- PMS2 | c.69C>T p.V23= | Silent (SNP) | VAF 338/586 reads (58%) | catalogued as COSV56150677; called by muse, mutect2, varscan2
- POGK | c.843C>T p.T281= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV63311563; called by muse, mutect2, varscan2
- POLR2C | c.447C>T p.L149= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs762783187, COSV54672630; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1773G>A p.K591= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as rs377463873, COSV53452773; called by muse, mutect2, varscan2
- PPP1R16B | c.198C>T p.F66= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as COSV55375283; called by muse, mutect2, varscan2
- PRAMEF19 | c.1347G>A p.R449= | Silent (SNP) | VAF 230/407 reads (57%) | called by muse, mutect2, varscan2
- PREX2 | c.3711G>A p.R1237= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV55748771; called by muse, mutect2, varscan2
- PRPF6 | c.1959C>T p.S653= | Silent (SNP) | VAF 98/259 reads (38%) | catalogued as rs757720133; called by muse, mutect2, varscan2
- PRUNE2 | c.990C>T p.I330= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs760960956; called by muse, mutect2
- PSD4 | c.138C>T p.F46= | Silent (SNP) | VAF 41/95 reads (43%) | catalogued as rs139939908; called by muse, mutect2, varscan2
- PSG9 | c.1068G>A p.T356= | Silent (SNP) | VAF 73/311 reads (23%) | catalogued as rs184658916, COSV52484944; called by muse, mutect2, varscan2
- PTPA | c.198C>T p.F66= | Silent (SNP) | VAF 70/129 reads (54%) | catalogued as rs781742495, COSV61234894; called by muse, mutect2, varscan2
- PTPDC1 | c.1866C>T p.S622= (on ENST00000375360 / NM_177995.3; = p.S674= on NM_152422.4) | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs1448107700, COSV56623005, COSV99997845; called by muse, mutect2, varscan2
- PTPRS | c.5253C>T p.I1751= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs372371666, COSV99508764; called by muse, mutect2
- QKI | c.439C>T p.L147= | Silent (SNP) | VAF 42/92 reads (46%) | catalogued as COSV51693576; called by muse, mutect2, varscan2
- RBM45 | c.270C>T p.C90= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV99617712; called by muse, mutect2, varscan2
- RD3 | c.567C>T p.F189= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as COSV65362273; called by muse, mutect2, varscan2
- REST | c.3055C>T p.L1019= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV58360622; called by muse, mutect2, varscan2
- RGS6 | c.567G>A p.R189= | Silent (SNP) | VAF 55/233 reads (24%) | catalogued as rs1316636403, COSV59566002; called by muse, mutect2, varscan2
- RHOB | c.111C>T p.T37= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as rs140649204; called by muse, mutect2, varscan2
- RIF1 | c.1407C>T p.S469= | Silent (SNP) | VAF 59/171 reads (35%) | catalogued as COSV54616932; called by muse, mutect2, varscan2
- RIPOR3 | c.1281C>T p.F427= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as COSV50388867; called by muse, mutect2, varscan2
- RMDN2 | c.804G>A p.L268= (on ENST00000354545 / NM_001322212.2; = p.L446= on NM_144713.5) | Silent (SNP) | VAF 64/128 reads (50%) | catalogued as COSV52224880; called by muse, mutect2, varscan2
- ROR1 | c.762C>T p.I254= | Silent (SNP) | VAF 122/216 reads (56%) | catalogued as COSV64287168; called by muse, mutect2, varscan2
- RP1L1 | c.966C>T p.S322= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as rs865791745, COSV66754878; called by muse, mutect2, varscan2
- SART3 | c.2103G>A p.E701= (on ENST00000228284; = p.E683= on NM_014706.4) | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as COSV57207286; called by muse, mutect2, varscan2
- SCN10A | c.3972G>A p.S1324= | Silent (SNP) | VAF 86/161 reads (53%) | catalogued as rs149883899; called by muse, mutect2, varscan2
- SDHC | c.426C>T p.G142= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100713672; called by muse, mutect2, varscan2
- SDHC | c.427C>T p.L143= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs748120641, COSV100713675; called by muse, mutect2, varscan2
- SDK2 | c.2127C>T p.I709= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV66185797; called by muse, mutect2, varscan2
- SEL1L3 | c.1671C>T p.I557= | Silent (SNP) | VAF 34/57 reads (60%) | catalogued as rs761382330, COSV53540713; called by muse, mutect2, varscan2
- SEZ6 | c.618C>T p.I206= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs553515418, COSV57978560; called by muse, mutect2, varscan2
- SFTPD | c.726G>A p.Q242= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV64852976; called by muse, mutect2, varscan2
- SIGLEC12 | c.1326G>A p.G442= (on ENST00000291707 / NM_053003.4; = p.G324= on NM_033329.2) | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs780261496, COSV52461408; called by muse, mutect2, varscan2
- SLC12A3 | c.615C>T p.F205= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as COSV52634884; called by muse, mutect2, varscan2
- SLC28A1 | c.1473C>T p.I491= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as COSV54478984; called by muse, mutect2, varscan2
- SLCO1B3 | c.1596G>A p.R532= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as rs914821884, COSV53931615; called by muse, mutect2, varscan2
- SLIT2 | c.891T>C p.N297= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as COSV56572003; called by muse, mutect2, varscan2
- SMOX | c.1653C>T p.F551= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV53864828; called by muse, mutect2, varscan2
- SNPH | c.258C>T p.I86= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV67870621; called by muse, mutect2, varscan2
- SNRNP200 | c.2715C>T p.I905= | Silent (SNP) | VAF 149/314 reads (47%) | catalogued as rs138641050, COSV60489521; called by muse, mutect2, varscan2
- SOGA1 | c.3606C>T p.S1202= | Silent (SNP) | VAF 42/79 reads (53%) | catalogued as rs748979592, COSV52918256, COSV99415621; called by muse, mutect2, varscan2
- SPAG17 | c.4887G>A p.K1629= | Silent (SNP) | VAF 35/131 reads (27%) | catalogued as COSV60458630; called by muse, mutect2, varscan2
- SPHKAP | c.1350C>T p.I450= | Silent (SNP) | VAF 90/164 reads (55%) | catalogued as rs748918142, COSV60878461; called by muse, mutect2, varscan2
- SPIRE2 | c.747C>T p.L249= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV65555716; called by muse, mutect2, varscan2
- STAB1 | c.7431G>T p.A2477= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV100195033; called by muse, mutect2, varscan2
- SYNE1 | c.8409G>A p.K2803= (on ENST00000367255 / NM_182961.4; = p.K2810= on NM_033071.3) | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as rs889204216, COSV54978510; called by muse, mutect2, varscan2
- SYNGR2 | c.255C>T p.F85= | Silent (SNP) | VAF 56/190 reads (29%) | catalogued as COSV56745714; called by muse, mutect2
- TACC2 | c.24G>C p.S8= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs886895560, COSV57755285; called by muse, mutect2, varscan2
- TADA1 | c.6G>A p.A2= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs774343116, COSV63310232; called by muse, mutect2, varscan2
- TAMALIN | c.1161C>T p.S387= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV53337263; called by muse, mutect2, varscan2
- TENT5A | c.1035G>A p.V345= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV60788102; called by muse, mutect2, varscan2
- THSD7B | c.4236G>A p.E1412= (on ENST00000272643; = p.E1410= on NM_001316349.2) | Silent (SNP) | VAF 103/216 reads (48%) | catalogued as COSV55685227, COSV99758030; called by muse, mutect2, varscan2
- TIAL1 | c.487T>C p.L163= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs930875790, COSV64843208; called by muse, mutect2, varscan2
- TMEM132B | c.1839C>T p.I613= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs370664891, COSV54755187; called by muse, mutect2, varscan2
- TMEM132B | c.2568G>A p.G856= | Silent (SNP) | VAF 43/63 reads (68%) | catalogued as COSV54752607; called by muse, mutect2, varscan2
- TMEM202 | c.276C>T p.Y92= | Silent (SNP) | VAF 53/110 reads (48%) | catalogued as rs142190891; called by muse, mutect2, varscan2
- TMEM63C | c.78G>A p.R26= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV53603555; called by muse, mutect2
- TMEM94 | c.1203C>T p.S401= | Silent (SNP) | VAF 35/48 reads (73%) | catalogued as COSV58595532; called by muse, mutect2, varscan2
- TOMM34 | c.921C>T p.N307= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV53840485; called by muse, mutect2, varscan2
- TRHR | c.966C>T p.L322= | Silent (SNP) | VAF 90/329 reads (27%) | catalogued as rs267601709, COSV100305111, COSV61234161; called by muse, mutect2, varscan2
- TRIM49 | c.1185C>T p.S395= | Silent (SNP) | VAF 46/79 reads (58%) | catalogued as COSV100316069; called by muse, mutect2, varscan2
- TRPC5 | c.1530G>A p.L510= | Silent (SNP) | VAF 81/89 reads (91%) | catalogued as COSV53290243; called by muse, mutect2, varscan2
- TTC8 | c.402C>T p.T134= (on ENST00000338104 / NM_001288781.1; = p.T144= on NM_144596.4) | Silent (SNP) | VAF 38/64 reads (59%) | catalogued as rs748561167, COSV100581344, COSV57629272; called by muse, mutect2, varscan2
- TTN | c.67776T>C p.T22592= (on ENST00000591111; = p.T15168= on NM_003319.4) | Silent (SNP) | VAF 45/150 reads (30%) | catalogued as COSV60052212; called by muse, mutect2, varscan2
- UGT2A1 | c.1566G>A p.K522= | Silent (SNP) | VAF 39/65 reads (60%) | catalogued as rs970963368, COSV54141432; called by muse, mutect2, varscan2
- USP29 | c.2724C>T p.I908= | Silent (SNP) | VAF 57/92 reads (62%) | catalogued as rs1303338871, COSV54142540, COSV99518597; called by muse, mutect2, varscan2
- UTP11 | c.723C>T p.S241= | Silent (SNP) | VAF 75/123 reads (61%) | catalogued as COSV65951373; called by muse, mutect2, varscan2
- VAC14 | c.1959G>A p.G653= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV55753516; called by muse, mutect2, varscan2
- VCAM1 | c.81C>T p.I27= | Silent (SNP) | VAF 58/239 reads (24%) | catalogued as rs769862238, COSV54119336, COSV54119728; called by muse, mutect2, varscan2
- VN1R4 | c.51G>A p.V17= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV60804990; called by muse, mutect2, varscan2
- VPS13D | c.10884A>G p.S3628= | Silent (SNP) | VAF 34/60 reads (57%) | catalogued as COSV50638106; called by muse, mutect2, varscan2
- VWF | c.6867C>T p.V2289= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV54620045; called by muse, mutect2, varscan2
- WWC1 | c.2754T>C p.F918= | Silent (SNP) | VAF 99/163 reads (61%) | catalogued as COSV54650721; called by muse, mutect2, varscan2
- XCR1 | c.993C>T p.S331= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV58569655; called by muse, mutect2, varscan2
- ZAN | c.4779C>T p.I1593= | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as COSV61808956; called by muse, mutect2, varscan2
- ZBED1 | c.1113C>T p.I371= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as rs771509152, COSV58133526; called by muse, mutect2, varscan2
- ZC3H12D | c.648G>A p.Q216= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs1399285970, COSV66324325; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1254C>T p.F418= | Silent (SNP) | VAF 52/192 reads (27%) | catalogued as COSV60156868; called by muse, mutect2, varscan2
- ZNF160 | c.960G>A p.K320= | Silent (SNP) | VAF 38/161 reads (24%) | catalogued as COSV100762337; called by muse, mutect2, varscan2
- ZNF559 | c.1581C>T p.T527= | Silent (SNP) | VAF 83/168 reads (49%) | catalogued as COSV57835579; called by muse, mutect2, varscan2
- ZNF682 | c.453G>A p.V151= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV62067020; called by muse, mutect2, varscan2
- ANKS1A | c.*2C>G | 3'UTR (SNP) | VAF 43/79 reads (54%) | catalogued as COSV100832452; called by muse, mutect2, varscan2
- CPLANE1 | c.*3208C>T | 3'UTR (SNP) | VAF 60/118 reads (51%) | catalogued as COSV57059701; called by muse, mutect2, varscan2
- DSCR4 | n.267C>T | RNA (SNP) | VAF 44/90 reads (49%) | catalogued as rs763998449, COSV60300161, COSV60302643; called by muse, mutect2, varscan2
- FAM228A | c.*2C>T | 3'UTR (SNP) | VAF 15/35 reads (43%) | catalogued as COSV99722539; called by muse, mutect2, varscan2
- KIR3DX1 | n.225C>T | RNA (SNP) | VAF 28/49 reads (57%) | catalogued as COSV55598294; called by muse, mutect2, varscan2
- LARS2 | c.*74G>A | 3'UTR (SNP) | VAF 62/106 reads (58%) | catalogued as COSV55527495; called by muse, mutect2, varscan2
- LEF1 | c.*52C>A | 3'UTR (SNP) | VAF 33/51 reads (65%) | catalogued as COSV99489609; called by muse, mutect2, varscan2
- LY9 | c.454+1787C>T | Intron (SNP) | VAF 38/217 reads (18%) | catalogued as COSV99626760; called by muse, varscan2
- MIR31 | n.70C>T | RNA (SNP) | VAF 53/77 reads (69%) | called by muse, mutect2, varscan2
- RPL7P3 | chr20:62570509 C>T | 5'Flank (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- RREB1 | c.3809-5834C>T | Intron (SNP) | VAF 25/53 reads (47%) | catalogued as COSV58557850; called by muse, mutect2, varscan2
- SLC17A3 | c.303+242C>T | Intron (SNP) | VAF 5/20 reads (25%) | catalogued as COSV57759997; called by muse, mutect2, varscan2
- SNORD116-27 | n.5C>T | RNA (SNP) | VAF 22/52 reads (42%) | catalogued as rs750880853; called by muse, mutect2, varscan2
- TUSC3 | c.1028+309C>T | Intron (SNP) | VAF 11/46 reads (24%) | catalogued as rs186255536; called by muse, mutect2, varscan2
- ZNF99 | c.*1056C>T | 3'UTR (SNP) | VAF 50/82 reads (61%) | catalogued as COSV101233741; called by muse, mutect2, varscan2
- ZNF99 | c.*282G>A | 3'UTR (SNP) | VAF 50/82 reads (61%) | catalogued as COSV68057962; called by muse, mutect2, varscan2
